Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6306, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6306-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. TERMINAL ILEUM AND RIGHT COLON
- B. GALLBLADDER

DIAGNOSIS:

- A. RIGHT COLON AND TERMINAL ILEUM, RESECTION:
- MODERATELY DIFFERENTIATED INFILTRATING COLONIC ADENOCARCINOMA (3.1 CM) EXTENDING INTO SUBSEROUSAL FAT. SEE TEMPLATE.
- SEVENTEEN BENIGN LYMPH NODES (0/17)
- MULTIPLE TUBULAR ADENOMAS
- SURGICAL MARGINS, SMALL BOWEL AND APPENDIX ARE NOT INVOLVED
- B. GALLBLADDER, EXCISION:
- CHRONIC CHOLELITHIASIS.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Right hemicolectomy
Tumor Site:	Ascending Colon
Tumor Configuration:	Exophytic
Tumor Size:	3.1 x 2.5 x 0.6 cm
Histological Type:	Adenocarcinoma
Histological Grade:	Well differentiated
Extent of Invasion:	Focal subserosal adipose tissue
Margins:	Uninvolved
Distance to Closest Margin:	Approximately 1.5 cm, radial
Angiolymphatic Invasion:	Indeterminate
Perineural Invasion:	Absent
Additional Findings:	Multiple tubular adenomas
Extent of Resection:	R0: Complete
Lymph Nodes:	Negative 0/17
Implants:	Absent
Pathological Stage:	pT2 N0 MX

SPECIMEN(S):

- A. TERMINAL ILEUM AND RIGHT COLON B. GALLBLADDER

CLINICAL HISTORY:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Colon, right and terminal ileum, resection: 3 cm mass in ascending colon-10 cm from distal margin and 14 cm from proximal margin.

By Dr, [REDACTED]

GROSS DESCRIPTION:

A. TERMINAL ILEUM AND RIGHT COLON

Received fresh is a curved segment of colon measuring approximately 24cm in length with a diameter up to 9.5cm. The serosal surface is unremarkable and there is an attached appendix measuring 6 cm in length with a diameter of 1.0cm. The appendix shows no gross abnormalities. The specimen is opened and the ileum measures 7.3 x 4.2 cm with the ascending colon measuring 19.5 x 8.2 cm. There is a 3.1 x 2.5 cm oval sessile firm mass present in the ascending colon which is located 6.2 cm from the ileocecal junction, 10.0 cm from the distal colonic margin and 14.0 cm from the proximal margin. The mesocolonic fat is inked black and on sectioning the mass, it appears to invade into the submucosa. There are additional polyps located in the ascending colon, ranging in size from 0.3 to 0.6cm.

Representative sections are submitted as follows:

- A1: proximal margin
- A2: distal margin
- A3: appendix
- A4: polyps
- A5-A9: mass including the deep margin

[page 2 of 2]
[REDACTED]

A10-A15: possible lymph nodes, ranging in size from 0.2 to 1.0cm.

A16: representative section of normal colon and normal ileum

A17: representative section of ileocecal junction

B. GALLBLADDER

Received in formalin and labeled as "gallbladder" is an opened pink-tan gallbladder, measuring 7.5 x 4.0 x 1.2cm. The serosal surface is smooth and is grossly unremarkable. The mucosal surface has a pink-tan coloration and a slightly granular/polypoid appearance. The gallbladder walls measure up to 0.2cm. No masses or lesions are seen. Also submitted is an irregularly shaped black-gold stone measuring approximately 7.0 x 5.0 x 4.2cm. Representative sections are submitted in blocks B1-B2.

[REDACTED]

Source: NCI Genomic Data Commons file 863ad095-35a3-4807-bcdc-4ce6d156380c (TCGA-G4-6306.563E9AA1-D970-4CA7-9A04-634F1EC8DC9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).